Somatic mutation profile of tumor specimen ASCProject_0289_T3_WES (aliquot ASCProject_0289_T3_WES_1) from CMI case ASCProject_0289, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 62.8 years (22,949 days).
Specimen ASCProject_0289_T3_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Chest Wall; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4fa2f085-d085-4e89-a78e-0893b842ce66.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0289_SALIVA (Saliva), aliquot ASCProject_0289_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d093ad44-194a-4a4b-b7cd-fa797a23824f

The open-access MAF lists 96 somatic variants for this specimen: 63 protein-altering or splice-affecting, 16 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 16, Frame Shift Del 10, Intron 9, RNA 5, 3'UTR 3, Nonsense Mutation 2, Nonstop Mutation 1, Splice Region 1, In Frame Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.215); catalogued as rs727503093, COSV54244375; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 231/341 reads (68%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.2211G>A p.A737= | Splice Region (SNP) | VAF 53/156 reads (34%) | catalogued as rs763404399; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALMS1 | c.3658C>T p.P1220S | Missense Mutation (SNP) | VAF 60/188 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs768322072; called by muse, mutect2, varscan2
- BTBD10 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.231); catalogued as rs200899824, COSV99533382; called by muse, mutect2, varscan2
- CAPNS1 | c.138_158del p.G50_G56del | In Frame Del (DEL) | VAF 38/120 reads (32%) | catalogued as rs779030286; called by mutect2, varscan2
- CYP4F2 | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as rs764924891; called by muse, varscan2
- EPB42 | c.275C>A p.A92E (on ENST00000441366 / NM_001114134.2; = p.A122E on NM_000119.3) | Missense Mutation (SNP) | VAF 75/166 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55752520; called by muse, mutect2, varscan2
- FLT4 | c.3208C>T p.R1070C | Missense Mutation (SNP) | VAF 318/377 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774554521, COSV56112322, COSV99987558; called by muse, mutect2, varscan2
- GRM7 | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); catalogued as rs375075667; called by muse, mutect2, varscan2
- H6PD | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.879); catalogued as rs149313646; called by muse, mutect2, varscan2
- INTS12 | c.494G>A p.C165Y | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100415783; called by muse, mutect2
- INTS4 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 26/97 reads (27%) | catalogued as rs763345688, COSV101417131; called by muse, mutect2, varscan2
- KCNK9 | c.803G>T p.R268L | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0.011); catalogued as rs201726948; called by muse, mutect2, varscan2
- MGA | c.7304G>A p.R2435Q (on ENST00000219905 / NM_001164273.1; = p.R2226Q on NM_001080541.2) | Missense Mutation (SNP) | VAF 102/318 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54951059, COSV54964414; called by muse, varscan2
- MUC4 | c.10174C>G p.P3392A | Missense Mutation (SNP) | VAF 120/907 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.55); catalogued as rs761575788, COSV57791841; called by muse, mutect2, varscan2
- NUMA1 | c.2947C>T p.R983W | Missense Mutation (SNP) | VAF 60/169 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs767012823, COSV61184204; called by muse, mutect2, varscan2
- OTOG | c.3105G>C p.M1035I | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61129222; called by muse, mutect2, varscan2
- SLITRK4 | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); catalogued as COSV100567576; called by muse, mutect2, varscan2
- SMPD3 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as rs376855372; called by muse, mutect2, varscan2
- TRRAP | c.8324C>T p.A2775V (on ENST00000359863 / NM_001244580.1; = p.A2757V on NM_003496.3) | Missense Mutation (SNP) | VAF 68/207 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.037); catalogued as rs764087337, COSV62849990; called by muse, mutect2, varscan2
- TTLL6 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1187599470, COSV64978613; called by muse, mutect2, varscan2
- TTN | c.6490G>A p.A2164T (on ENST00000591111; = p.A2118T on NM_003319.4) | Missense Mutation (SNP) | VAF 109/298 reads (37%) | PolyPhen probably damaging (0.966); catalogued as rs56285559, CM1510358; ClinVar: likely benign; called by muse, mutect2, varscan2
- UGT8 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.067); catalogued as rs374700060; called by muse, mutect2, varscan2
- ZBTB48 | c.232G>T p.D78Y | Missense Mutation (SNP) | VAF 144/315 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1417978097; called by muse, mutect2, varscan2
- ZNHIT6 | c.1079T>C p.I360T | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs146289461; called by muse, mutect2, varscan2
- ADARB2 | c.2039G>A p.G680D | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.149); called by mutect2, varscan2
- AMER1 | c.146C>A p.P49Q | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ATP8B4 | c.2464A>G p.M822V | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC27 | c.861+1del | Frame Shift Del (DEL) | VAF 28/76 reads (37%) | called by mutect2, pindel, varscan2
- CFAP54 | c.1538A>C p.Q513P | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- COL5A1 | c.1332_1332+1del | Frame Shift Del (DEL) | VAF 8/21 reads (38%) | called by mutect2, pindel, varscan2
- ESCO2 | c.1567C>A p.Q523K | Missense Mutation (SNP) | VAF 93/146 reads (64%) | SIFT tolerated (0.22); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- GPR68 | c.518_519del p.F173* | Frame Shift Del (DEL) | VAF 57/295 reads (19%) | called by mutect2, pindel, varscan2
- GYG1 | c.322C>G p.L108V | Missense Mutation (SNP) | VAF 90/257 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- HSD17B2 | c.1122del p.R375Efs*3 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by mutect2, pindel, varscan2
- HTR1F | c.934A>G p.K312E | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- IGFBP7 | c.791_792del p.T264Sfs*3 | Frame Shift Del (DEL) | VAF 32/123 reads (26%) | called by mutect2, pindel, varscan2
- IL21 | c.137T>G p.V46G | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KCNMA1 | c.3022G>A p.D1008N (on ENST00000286628 / NM_001161352.2; = p.D950N on NM_002247.4) | Missense Mutation (SNP) | VAF 88/265 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KLHL2 | c.1770del p.D590Efs*16 | Frame Shift Del (DEL) | VAF 57/187 reads (30%) | called by mutect2, pindel, varscan2
- LMOD1 | c.1130_1131del p.F377Cfs*78 | Frame Shift Del (DEL) | VAF 77/318 reads (24%) | called by mutect2, pindel, varscan2
- LUZP2 | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 39/120 reads (33%) | called by muse, mutect2, varscan2
- MCF2 | c.1022G>T p.G341V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- NFAT5 | c.634G>T p.V212F | Missense Mutation (SNP) | VAF 71/199 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- NTRK2 | c.1303G>T p.A435S | Missense Mutation (SNP) | VAF 83/256 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- PADI6 | c.2084A>T p.*695Lext*73 | Nonstop Mutation (SNP) | VAF 31/68 reads (46%) | called by muse, mutect2
- PLOD1 | c.136C>A p.R46S | Missense Mutation (SNP) | VAF 91/219 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PPM1E | c.576del p.T193Lfs*7 | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | called by mutect2, pindel, varscan2
- PSD | c.24C>A p.F8L | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- QSER1 | c.953del p.S318Lfs*2 (on ENST00000399302; = p.S447Lfs*2 on NM_001076786.3) | Frame Shift Del (DEL) | VAF 50/120 reads (42%) | called by mutect2, pindel, varscan2
- RAB40AL | c.30_63del p.Y11Tfs*4 | Frame Shift Del (DEL) | VAF 20/126 reads (16%) | called by mutect2, pindel
- RAD51AP2 | c.1039A>T p.S347C | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RASIP1 | c.1759G>A p.A587T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.082); called by mutect2, varscan2
- RNF214 | c.1943C>G p.S648C | Missense Mutation (SNP) | VAF 63/178 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- SLC26A7 | c.1269G>C p.Q423H | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SRGAP1 | c.1754G>C p.R585P | Missense Mutation (SNP) | VAF 113/313 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYTL1 | c.1468G>C p.A490P (on ENST00000543823; = p.A478P on NM_032872.3) | Missense Mutation (SNP) | VAF 73/193 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- TACC2 | c.4226G>T p.R1409M | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- TM7SF3 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM266 | c.815_820dup p.D272_L273dup | In Frame Ins (INS) | VAF 23/74 reads (31%) | called by mutect2, varscan2
- USP15 | c.2117G>A p.G706E (on ENST00000280377 / NM_001351159.2; = p.G677E on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/205 reads (30%) | SIFT tolerated (0.96); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- ZSCAN4 | c.769T>C p.S257P | Missense Mutation (SNP) | VAF 70/200 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DUS3L | c.924C>T p.Y308= | Silent (SNP) | VAF 49/128 reads (38%) | catalogued as rs776236795; called by muse, mutect2, varscan2
- EHBP1L1 | c.3510C>T p.P1170= | Silent (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- GRM5 | c.369A>G p.E123= | Silent (SNP) | VAF 48/209 reads (23%) | catalogued as COSV100552424; called by muse, mutect2, varscan2
- HKDC1 | c.2487G>A p.A829= | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as rs749311990, COSV100664822, COSV63575579; called by muse, mutect2, varscan2
- KCNV2 | c.717C>T p.Y239= | Silent (SNP) | VAF 90/209 reads (43%) | catalogued as rs777741747; called by muse, mutect2, varscan2
- MAK | c.1647C>G p.S549= | Silent (SNP) | VAF 83/243 reads (34%) | catalogued as COSV100504783; called by muse, mutect2, varscan2
- MYLK3 | c.2436A>G p.L812= | Silent (SNP) | VAF 41/130 reads (32%) | called by muse, mutect2, varscan2
- NTSR2 | c.385C>T p.L129= | Silent (SNP) | VAF 49/90 reads (54%) | called by muse, mutect2, varscan2
- OR2M3 | c.151C>T p.L51= | Silent (SNP) | VAF 38/142 reads (27%) | catalogued as COSV101513398; called by muse, mutect2, varscan2
- PCDHA13 | c.2178G>A p.P726= | Silent (SNP) | VAF 144/180 reads (80%) | catalogued as rs1474628802, COSV56501101; called by muse, mutect2, varscan2
- PRPS1L1 | c.165C>T p.I55= | Silent (SNP) | VAF 254/575 reads (44%) | catalogued as rs749613723, COSV72649918; called by muse, mutect2, varscan2
- RASGEF1B | c.615C>T p.D205= | Silent (SNP) | VAF 44/142 reads (31%) | called by muse, mutect2, varscan2
- RBBP6 | c.1644G>A p.P548= | Silent (SNP) | VAF 44/95 reads (46%) | catalogued as rs771063330, COSV60505694; called by muse, mutect2, varscan2
- RSRC2 | c.1023C>A p.G341= | Silent (SNP) | VAF 52/116 reads (45%) | called by muse, mutect2, varscan2
- SDK2 | c.810C>A p.T270= | Silent (SNP) | VAF 32/107 reads (30%) | called by muse, mutect2, varscan2
- SPRTN | c.369C>T p.N123= | Silent (SNP) | VAF 37/136 reads (27%) | catalogued as rs147506920; ClinVar: likely benign; called by muse, mutect2, varscan2
- CARD14 | c.1851+84C>T | Intron (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2, varscan2
- DOCK6 | c.45-54C>G | Intron (SNP) | VAF 23/71 reads (32%) | called by muse, mutect2, varscan2
- DPPA3P2 | n.639del | RNA (DEL) | VAF 77/256 reads (30%) | called by mutect2, pindel, varscan2
- FAM124A | c.101-6153G>A | Intron (SNP) | VAF 13/37 reads (35%) | catalogued as rs1416021182; called by muse, mutect2, varscan2
- FIGNL2 | c.*8C>T | 3'UTR (SNP) | VAF 48/133 reads (36%) | catalogued as rs1306998744; called by muse, mutect2, varscan2
- FRA10AC1 | c.*19C>A | 3'UTR (SNP) | VAF 41/126 reads (33%) | called by muse, mutect2, varscan2
- G6PD | c.771-52C>A | Intron (SNP) | VAF 25/95 reads (26%) | called by muse, mutect2, varscan2
- GTF3C2 | c.-25+628T>G | Intron (SNP) | VAF 60/193 reads (31%) | called by muse, mutect2, varscan2
- GYS2 | c.1809+27G>A | Intron (SNP) | VAF 35/107 reads (33%) | called by muse, mutect2, varscan2
- IRAK3 | c.*1A>G | 3'UTR (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2, varscan2
- KRT8P11 | n.113C>A | RNA (SNP) | VAF 68/203 reads (33%) | called by muse, mutect2, varscan2
- NAE1 | c.54-1196C>T | Intron (SNP) | VAF 40/94 reads (43%) | catalogued as rs781046056; called by muse, mutect2, varscan2
- NOP2 | c.475-200T>A | Intron (SNP) | VAF 65/174 reads (37%) | called by muse, mutect2, varscan2
- NSMF | c.1047+44A>T | Intron (SNP) | VAF 72/170 reads (42%) | called by muse, mutect2, varscan2
- OR7E5P | n.187del | RNA (DEL) | VAF 45/131 reads (34%) | called by mutect2, pindel, varscan2
- SNORD114-31 | n.9C>T | RNA (SNP) | VAF 42/108 reads (39%) | catalogued as rs753645973; called by muse, mutect2, varscan2
- XIST | n.11190C>G | RNA (SNP) | VAF 82/225 reads (36%) | called by muse, mutect2, varscan2
